Gene-level copy-number profile of tumor specimen TCGA-06-A7TK-01A from TCGA case TCGA-06-A7TK, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 64.8 years (23,674 days).
Specimen TCGA-06-A7TK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.e5e96553-a283-4ed0-b2ba-f7d1e366cd21.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-A7TK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/06f692f0-ca04-42c6-91d9-909484823e37

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,794; copy number 2: 46,267; copy number 3: 4,468; copy number 4: 103; copy number 5: 126; copy number 6: 16; copy number 24: 24; copy number 56: 8; copy number 57: 10; copy number 79: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-A7TK-01A-21D-A390-01): tumor purity 0.69, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 187 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:3,752,518–7,621,450, 142 genes, copy number 5–6 (broad region; genes not listed).
- chr12:57,615,280–57,846,729, 24 genes, copy number 24 (within-gene range 1–24): AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr12:63,844,700–64,162,217, 1 gene, copy number 56 (within-gene range 1–56): SRGAP1.
- chr12:64,032,412–64,222,296, 7 genes, copy number 56 (within-gene range 1–56): AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P.
- chr12:68,674,371–68,850,686, 10 genes, copy number 57: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:70,239,114–70,354,993, 3 genes, copy number 79: AC092881.2, CNOT2, AC092881.1.

Autosomal genes at a single copy (total copy number 1): 6,407. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
